Surgical pathology report (de-identified scan), TCGA case TCGA-LP-A5U2, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site ILSBIO, specimen TCGA-LP-A5U2-01A (Primary Tumor).

[page 1 of 7]
Clinical Case Report

(For Collection of Cancerous Tissue)

ICD-0-3
CQCF: adenocarcinoma, endocervical type
8384/3

Path: adenocarcinoma, NOS 8140/3

Site: cervix, NOS C53.9, 1w
3/14/13

Informed Consent

I personally informed this patient that a specimen(s) would be collected to be used for research purposes. I reviewed the **RESEARCH SUBJECT INFORMATION AND CONSENT FORM** with the patient and answered any questions the patient had. The patient then signed the consent form as a free and voluntary act. A copy of this informed consent document will be retained at our institution.

Name of Physician or Study Coordinator

Signature

Date

Clinical Information

GENERAL INFORMATION				
Date of Birth (mm/dd/yyyy)	Height	☐ Single ☒ Married ☐ Divorced ☐ Widow	Race	Temperature
Gender	Weight		Blood Pressure	Heart Rate
☐ Male ☒ Female	51		110/70	70

HISTORY OF PRESENT ILLNESS	
Chief Complaints:	- 13 weeks of gestational age. - abnormal vaginal bleeding.
Symptoms:	vaginal bleeding during pregnancy.
Clinical Findings:	- 13 weeks of gestational age - vulva and vagina were normal. - mass seen in posterior lip
Performance Scale (Karnofsky Score): ☐ 100 Asymptomatic ☒ 80-90 Symptomatic but Fully Ambulatory ☐ 60-70 Symptomatic, in bed less than 50% of day ☐ 40-50 Symptomatic, in bed more than 50% of day, but not bed ridden ☐ 20-30 Bed Ridden	

CURRENT MEDICATIONS				
Drug	Dose	Route	Frequency	Date (mm/dd/yyyy)
MS				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /

[page 2 of 7]
PAST MEDICAL HISTORY			
Diagnosis/Disease/Disorder/Injury	Diagnosis Date	Treatment	Status
normal			

OB/GYN HISTORY			
Menopausal Status	Date of First Menses	# of Pregnancies	
☐ Pre-menopausal		0	
☐ Peri-Menopausal	Date of Last Menses	# of Live Births	
☐ Post-menopausal		0	
Birth Control: ☐ Condom ☐ Oral Contraceptive ☐ IUD		☐ Hormone Replacement Therapy:	
☐ Other: no use		no	

SOCIAL HISTORY				
Occupation:		Environmental Hazards:		
		no		
Smoking History				
Current Status	TYPE	Packs/day	Duration	When Quit
☐ YES ☒ NO			(yrs)	(yr)
Alcohol Consumption				
Current Status	TYPE	Drinks/day	Duration	When Quit
☐ YES ☒ NO			(yrs)	(yr)
Drug Use				
Current Status	TYPE	Frequency	Duration	When Quit
☐ YES ☒ NO			(yrs)	(yr)

FAMILY MEDICAL HISTORY		
Relative	Diagnosis	Age of Diagnosis
normal		

LAB DATA						
Test	Result	Date	Test	Result	Date	
HIV	☒ Negative ☐ Positive:		CEA	☐ Negative ☐ Positive:		no
Hep B	☒ Negative ☐ Positive:		CA 15-3	☐ Negative ☐ Positive:		no
Hep C	☐ Negative ☐ Positive:		CA 19-9	☐ Negative ☐ Positive:		no
AFP	☐ Negative ☐ Positive:		PSA	☐ Negative ☐ Positive:		no
Other:	☐ Negative ☐ Positive:		Other:	☐ Negative ☐ Positive:		no
B/T Cell Markers:						

[page 3 of 7]
DIAGNOSTIC STUDIES		
Study	Results	Date
Ultrasound	pregnancy / fetal age ~ 13 week	
X-Ray	no	
CT	no	
Endoscopy	no	
MRI	no	
Biopsy	invasive adenocarcinoma	

CLINICAL DIAGNOSIS	
Preoperative Clinical Diagnosis	
cervical cancer.	
Location of Suspected Involved Lymph Nodes	Location of Suspected Distant Metastasis
no	no
Clinical Staging	
T N M	Stage: T1b N0 M0
Date of Diagnosis	

Treatment Information

= IB

SURGICAL TREATMENT			
Procedure			Date of Procedure
Wertheim - Meigs			
Primary Tumor			
Organ	Detailed Location	Size	
CEX Vx	posterior lip and endocervical	cm	
Extension of Tumor			4 x 3 x 3 cm
inv. mus.			
Lymph Nodes			
Description	Location of Lymph Nodes	# of Lymph Nodes	
Palpable, Non-Dissected Lymph Nodes	no	no	
Dissected Lymph Nodes	pelvic	7	
Distant Metastasis			
Organ	Detailed Location	Size	
no			
Surgical Staging			
T N M	Stage: T2a N1 Mx = II B		

NEOADJUVANT THERAPY (Chemo, Radiation, Immuno, Hormonal, or Molecular)				
Drug/Treatment	Dose	Route	Frequency	Date (mm/dd/yyyy)
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /

[page 4 of 7]
Pathology Form

Specimen Information

Collected by: _

_____ Date:

Time: _

Preserved by: _____

_____ Date:

Time: _

SPECIMEN TYPE (# of samples provided)							
Frozen		Paraffin Block		Blood/Serum/Plasma		Slide	
Diseased	Normal	Diseased	Normal	Diseased	Normal	Diseased	Normal
4	no	4	no	1		4	
Time to LN2		Time to Formalin		Time to LN2			
15 min		20 min		15 min			

PATHOLOGICAL DESCRIPTION			
Primary Tumor			
Organ	Size	Extension of Tumor	Distance to NAT
Cervix	4 x 3 x 3 cm	Isthmus	0 cm
Lymph Nodes			
Location	# Examined	# Metastasized	
pelvis	7	2	
Distant Metastasis			
Organ	Detailed Location	Size	
no			
Pathological Staging			
pT	N	M	Stage: pT2a N1 Mx = II B
Notes:			

[page 5 of 7]
Microscopic Description

Histological Pattern											
Cell Distribution			+ -		Structural Pattern			+ -		+ -	
Diffuse			+	-	Streaming			+	-		
Mosaic			+	-	Storiform			+	-		
Necrosis			+	-	Fibrosis			+	-		
Lymphocytic Infiltration			+	-	Palisading						+
Vascular Invasion			+	-	Cystic Degeneration			+	-		
Clusterized			+	-	Bleeding			+	-		
Alveolar Formation			+	-	Myxoid Change						+
Indian File				+	Psammoma/Calcification						+

Cellular Differentiation											
Squamous			Adenomatous			Sarcomatous			Lymphomatous		
	+	-		+	-		+	-		+	-
Squamoid Cell		+	Glandular cell	+		Round Cell		+	Large Cell		+
Spindle Cell	+	+	Cell Stratification	+		Fibroblast		+	Small Cell		+
Keratin		+	Secretion	+		Osteoblast		+	RS Cell/RS Like		+
Desmosome		+	Intracyt. Vacuole	+		Lipoblast		+	Inflam. Cell		+
Pearl		+	Gland formation	+		Myoblast		+	Plasma Cell		+

Cellular Differentiation: Well Moderate Poor *f*

Nuclear Appearance				
Nuclear Atypia:	0	I	II	III
Aniso Nucleosis			+	
Hyperchromatism			+	
Nucleolar Prominent				+
Multinucleated Giant Cell		+		
Mitotic Activity			+	
Nuclear Grade:			+	

IHC Data			
Marker	Result	Value	Date
ER	☐ Negative ☐ Positive	no	
PR	☐ Negative ☐ Positive	no	
Her-2/neu	☐ Negative ☐ Positive	no	
B-Cell Marker	☐ Negative ☐ Positive	no	
T-Cell Marker	☐ Negative ☐ Positive	no	
Other:	☐ Negative ☐ Positive	no	
Other:	☐ Negative ☐ Positive	no	

Final Pathology Report

Histological Diagnosis: Adeno Carcinoma Grade: II

Comments: could not exclude Adeno & squamous carcinoma
per TSS on 2/15/13 - no squamous cell.
BCR

Principal Investigator

Pathologist

Date

[page 6 of 7]
Consolidated Pathology Diagnosis

Histological Pattern											
Cell Distribution			Structural Pattern			Cellular Differentiation			Nuclear Appearance		
	+	-		+	-		+	-		+	-
Diffuse		☒	Streaming			Squamous			Adenomatous		
Mosaic	☒		Storiform			Squamoid Cell			Glandular cell	☒	
Necrosis		☒	Fibrosis			Spindle Cell			Cell Stratification	☒	
Lymphocytic Infiltration	☒		Palisading			Keratin			Secretion	☒	
Vascular Invasion		☒	Cystic Degeneration			Desmosome			Intracyt. Vacuole	☒	
Clusterized		☒	Bleeding			Pearl			Gland formation	☒	
Alveolar Formation		☒	Myxoid Change			Cellular Differentiation: ☐ Well ☐ Moderate ☒ Poor					
Indian File		☒	Psammoma/Calcification			Nuclear Appearance					
						0	I	II	III		
Aniso Nucleosis									☒		
Hyperchromatism									☒		
Nucleolar Prominent									☒		
Multinucleated Giant Cell									☒		
Mitotic Activity									☒		
Nuclear Grade:									☒		

Final Pathology Report

Histological Diagnosis: Adenocarcinoma **Grade:** 3

Comments:

D₁ 75% D₂ 60% D₃ 65% D₄ 55%

Director, Pathology

TSS submitted dx discrepancy from stating
dx as "adenocarcinoma, endocervical type".
BCK

Date

[page 7 of 7]
TCGA Pathologic Diagnosis Discrepancy Form

V4.00

Instructions: The TCGA Pathologic Diagnosis Discrepancy Form should be completed when the pathologic diagnosis documented on the initial pathology report for a case submitted for TCGA is inconsistent with the diagnosis provided on the Case Quality Control Form completed for the submitted case.

Tissue Source Site (TSS): _____ TSS Identifier: _____ TSS Unique Patient Identifier: _____

Completed By (Interviewer Name on OpenClinica): _____ Completed Date: _____

Diagnosis Information

#	Data Element	Entry Alternatives	Working Instructions
1	Pathologic Diagnosis Provided on Initial Pathology Report	Adenocarcinoma	Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.
2	Histologic features of the sample provided for TCGA, as reflected on the CQCF.	Endocervical Adenocarcinoma	Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

Discrepancy between Pathology Report and Case Quality Control Form

3	Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form.	Adenocarcinoma of the cervix implies endocervical type unless otherwise specified. Both diagnosis are equivalent.	Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.
4	Name of TSS Reviewing Pathologist or Biorepository Director		Provide the name of the pathologist who reviewed this case for TCGA.

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled.

TSS Reviewing Pathologist or Biorepository Director

Date

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled. The Attending Pathologist or the Department Chairman has been informed or is aware of the above discrepancy in diagnoses.

Principal Investigator Signature

Date

Source: NCI Genomic Data Commons file 8b54d595-95b7-44a3-9549-5fa9bb6f5456 (TCGA-LP-A5U2.21CF3259-2E5C-48A6-B6BC-094001C4DB87.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).